Surgical pathology report (de-identified scan), TCGA case TCGA-41-2575, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-2575-01A (Primary Tumor).

SPECIMEN

- A. Right frontal tumor
- B. Right frontal tumor for Tissue Procurement
- C. Right frontal tumor

CLINICAL NOTES

PRE-OP DIAGNOSIS: Glioblastoma multiforme
CLINICAL HISTORY: History of brain biopsy [REDACTED].

FROZEN SECTION DIAGNOSIS

A - At least grade III astrocytoma. [REDACTED]

GROSS DESCRIPTION

- A. Received fresh for frozen section labeled "right frontal tumor." It consists of a fragment of soft glistening tan tissue measuring 0.8 x 0.6 x 0.3 cm. A touch preparation is made and the entire sample is submitted for frozen section.
- B. Entire specimen submitted for Tissue Procurement.
- C. Received in formalin labeled "right frontal tumor" are multiple pink-tan yellow irregular soft tissue fragments which have an aggregate measurement of 2.5 x 2.5 x 0.5 cm. The specimens are entirely submitted in one cassette. AS-1.
- [REDACTED]
- [REDACTED]

MICROSCOPIC DESCRIPTION

A, C. This is a markedly cellular astrocytic neoplasm. The tumor cells are pleomorphic with frequent mitoses. Neovascularization and pseudopalisading necrosis are also present. The features are compatible with glioblastoma multiforme, astrocytoma grade IV.

MICROSCOPIC DESCRIPTION

4x2, 14, 65

DIAGNOSIS

- A, C. Right frontal tumor, biopsy - Glioblastoma multiforme, astrocytoma grade IV.
- B. This specimen was sent in its entirety for Tissue Procurement.
- [REDACTED]

Source: NCI Genomic Data Commons file 7833197c-53c7-4428-8129-84d83fcadf10 (TCGA-41-2575.7F1E7294-3F10-40FD-AB3E-D8AD2AF07E5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).